Somatic mutation profile of tumor specimen ALCH-B47R-TTP1-A (aliquot ALCH-B47R-TTP1-A-2-0-D-A80E-36) from ALCHEMIST case ALCH-B47R, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.3 years (22,010 days).
Specimen ALCH-B47R-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d5a1ab7d-afc0-41c2-bc56-df198df8ee65.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B47R-NB1-A (Blood Derived Normal), aliquot ALCH-B47R-NB1-A-1-0-D-A80E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/80dacf09-ddcf-4a87-8265-7ce817e2d67c

The open-access MAF lists 373 somatic variants for this specimen: 252 protein-altering or splice-affecting, 72 silent, 49 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 221, Silent 72, Nonsense Mutation 21, Intron 11, 5'UTR 10, 3'UTR 9, RNA 8, 5'Flank 7, Splice Site 5, 3'Flank 4, Frame Shift Del 3, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 28/384 reads (7%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- SOX5 | c.1711C>T p.R571W | Missense Mutation (SNP) | VAF 21/193 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1565669640; ClinVar: likely pathogenic; called by muse, mutect2
- AC004593.2 | c.1351G>T p.A451S | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.125); catalogued as COSV99764363; called by muse, mutect2
- ACAN | c.1642G>A p.D548N | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.217); catalogued as COSV61360954; called by muse, mutect2
- ADAMTS12 | c.4066C>A p.P1356T | Missense Mutation (SNP) | VAF 97/316 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV61266394, COSV61279109; called by muse, mutect2, varscan2
- AKAP9 | c.9994C>T p.R3332* (on ENST00000359028; = p.R3308* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 40/559 reads (7%) | catalogued as rs771217988, COSV62341755; called by muse, mutect2
- APOB | c.471G>C p.K157N | Missense Mutation (SNP) | VAF 16/566 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1386840203, COSV51931334; called by muse, mutect2
- ATP7B | c.673G>C p.E225Q | Missense Mutation (SNP) | VAF 27/382 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.04); catalogued as COSV54441034; called by muse, mutect2
- BACH2 | c.2161G>A p.E721K | Missense Mutation (SNP) | VAF 11/152 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.198); catalogued as rs1346571372, COSV57591784; called by muse, mutect2
- BBOX1 | c.1107G>T p.W369C | Missense Mutation (SNP) | VAF 20/374 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54189551; called by muse, mutect2
- BCO2 | c.1701G>T p.Q567H | Missense Mutation (SNP) | VAF 18/320 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as COSV63062724; called by muse, mutect2
- C1orf167 | c.1601C>T p.A534V | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT tolerated (0.07); catalogued as rs1318139291; called by muse, mutect2
- CA8 | c.775G>T p.G259W | Missense Mutation (SNP) | VAF 20/599 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58771639; called by muse, mutect2
- CCDC33 | c.2075C>T p.T692I | Missense Mutation (SNP) | VAF 32/392 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.147); catalogued as rs777345155; called by muse, mutect2
- CCDC88C | c.2995G>C p.E999Q | Missense Mutation (SNP) | VAF 24/213 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.756); catalogued as COSV66237545; called by muse, mutect2, varscan2
- CCN2 | c.511G>C p.D171H | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as rs1171937033, COSV63466760; called by muse, mutect2
- CDH12 | c.722A>T p.D241V | Missense Mutation (SNP) | VAF 39/187 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101202953; called by muse, mutect2, varscan2
- CEP85L | c.191G>T p.G64V | Missense Mutation (SNP) | VAF 30/264 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100821491; called by muse, mutect2
- CHIT1 | c.521G>T p.G174V | Missense Mutation (SNP) | VAF 40/700 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV55147741; called by muse, mutect2
- CHST3 | c.1127G>T p.R376L | Missense Mutation (SNP) | VAF 13/212 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as COSV64150771; called by muse, mutect2
- CNTN4 | c.790G>T p.G264* | Nonsense Mutation (SNP) | VAF 13/304 reads (4%) | catalogued as COSV61880971; called by muse, mutect2
- COL1A2 | c.2668G>T p.A890S | Missense Mutation (SNP) | VAF 53/525 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs755962414; called by muse, mutect2, varscan2
- COL6A6 | c.2764G>T p.E922* | Nonsense Mutation (SNP) | VAF 7/140 reads (5%) | catalogued as rs1372372967; called by muse, mutect2
- CUBN | c.1813G>T p.G605W | Missense Mutation (SNP) | VAF 12/320 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64724617; called by muse, mutect2
- CUX2 | c.1940C>T p.S647L | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1397629871; called by muse, mutect2, varscan2
- DACH2 | c.161G>T p.S54I | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.773); catalogued as COSV64190006; called by muse, mutect2, varscan2
- DACH2 | c.1456G>T p.E486* | Nonsense Mutation (SNP) | VAF 28/176 reads (16%) | catalogued as COSV64165324; called by muse, mutect2, varscan2
- DCAF8L2 | c.265G>T p.D89Y | Missense Mutation (SNP) | VAF 21/237 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1294485367; called by muse, mutect2
- DLGAP4 | c.529G>T p.G177C | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); catalogued as COSV59423712; called by muse, mutect2, varscan2
- DNAH9 | c.5331G>T p.M1777I | Missense Mutation (SNP) | VAF 26/312 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.881); catalogued as COSV52377069; called by muse, mutect2
- FAT1 | c.4207G>A p.D1403N | Missense Mutation (SNP) | VAF 36/262 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as rs560351512, COSV71675908; called by muse, mutect2, varscan2
- FLG | c.2603G>A p.G868E | Missense Mutation (SNP) | VAF 42/658 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.071); catalogued as rs760204561, COSV64243215; called by muse, mutect2
- FMR1NB | c.191G>C p.R64P | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.221); catalogued as COSV65070953; called by muse, mutect2, varscan2
- GALNTL6 | c.1240G>T p.D414Y | Missense Mutation (SNP) | VAF 67/337 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72490023; called by muse, mutect2, varscan2
- GOLGA6L6 | c.2002C>A p.Q668K | Missense Mutation (SNP) | VAF 20/672 reads (3%) | SIFT tolerated (0.27); PolyPhen benign (0.037); catalogued as rs1344580206; called by muse, mutect2
- IL10RA | c.628G>T p.A210S | Missense Mutation (SNP) | VAF 23/318 reads (7%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs779757879; called by muse, mutect2
- KANK4 | c.2468A>G p.N823S | Missense Mutation (SNP) | VAF 37/262 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.219); catalogued as rs1422526495; called by muse, mutect2, varscan2
- KLK14 | c.146G>T p.R49L | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.672); catalogued as rs775349360; called by muse, mutect2, varscan2
- LRP1B | c.12575C>A p.A4192D | Missense Mutation (SNP) | VAF 18/378 reads (5%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV101252989; called by muse, mutect2
- MAP4K5 | c.109-2A>G p.X37_splice | Splice Site (SNP) | VAF 20/253 reads (8%) | catalogued as rs1398403258; called by muse, mutect2
- MET | c.2547G>C p.M849I | Missense Mutation (SNP) | VAF 25/188 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as rs747989932, COSV59271846; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO7A | c.722G>T p.R241L | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CM071027, CM1110176, COSV68683548; called by muse, mutect2
- NRXN3 | c.1692G>T p.M564I (on ENST00000557594 / NM_001272020.2; = p.M988I on NM_004796.6) | Missense Mutation (SNP) | VAF 27/199 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs1369895880; called by muse, mutect2, varscan2
- NUF2 | c.313G>C p.E105Q | Missense Mutation (SNP) | VAF 18/264 reads (7%) | SIFT tolerated (0.77); PolyPhen benign (0.024); catalogued as COSV54844239; called by muse, mutect2
- OR5J2 | c.909G>T p.R303S | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as COSV56623317; called by muse, mutect2, varscan2
- PAX3 | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 26/550 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV51336858; called by muse, mutect2
- PLCH1 | c.4396C>G p.Q1466E (on ENST00000340059 / NM_001130960.2; = p.Q1458E on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/200 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV58209628; called by muse, mutect2, varscan2
- PRDX6 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.254); catalogued as rs770150248; called by muse, mutect2
- RYR1 | c.2551G>T p.V851L | Missense Mutation (SNP) | VAF 27/240 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.29); catalogued as rs375669412; called by muse, mutect2, varscan2
- RYR2 | c.12920G>T p.R4307L | Missense Mutation (SNP) | VAF 23/176 reads (13%) | SIFT tolerated (0.69); PolyPhen benign (0.005); catalogued as COSV63684322, COSV63691311; called by muse, mutect2
- SBK1 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.079); catalogued as rs1240359041; called by muse, mutect2
- SEMA6C | c.1071G>C p.W357C | Missense Mutation (SNP) | VAF 33/309 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100501234; called by muse, mutect2, varscan2
- SGSM1 | c.2407G>A p.V803M (on ENST00000400359 / NM_001039948.4; = p.V742M on NM_133454.3) | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV100771845; called by muse, mutect2
- SLA | c.806C>G p.S269* (on ENST00000338087 / NM_001045556.3; = p.S309* on NM_006748.4) | Nonsense Mutation (SNP) | VAF 79/425 reads (19%) | catalogued as COSV99603035; called by muse, mutect2, varscan2
- SLC12A3 | c.391G>T p.E131* | Nonsense Mutation (SNP) | VAF 32/391 reads (8%) | catalogued as CM1510317; called by muse, mutect2
- SOHLH1 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 18/376 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100039992, COSV53681013; called by muse, mutect2
- SOST | c.351C>A p.N117K | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1429489212, COSV100059761; called by muse, mutect2, varscan2
- STARD9 | c.8119G>C p.D2707H | Missense Mutation (SNP) | VAF 19/402 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as rs1313985808; called by muse, mutect2
- STYXL1 | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 15/305 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as rs782034758; called by muse, mutect2
- THOP1 | c.1961C>T p.A654V | Missense Mutation (SNP) | VAF 18/211 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs868712350; called by muse, mutect2
- TMEM225 | c.174G>T p.W58C | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66693048; called by muse, mutect2
- TP53 | c.1051A>T p.K351* | Nonsense Mutation (SNP) | VAF 44/310 reads (14%) | catalogued as COSV52745104, COSV52944131; called by muse, mutect2, varscan2
- TRPM6 | c.4501G>T p.D1501Y | Missense Mutation (SNP) | VAF 23/482 reads (5%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as COSV100667005; called by muse, mutect2
- UNC13C | c.5546G>T p.S1849I | Missense Mutation (SNP) | VAF 13/240 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV52894782; called by muse, mutect2
- UNC5C | c.785G>A p.G262D | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71661099; called by muse, mutect2, varscan2
- UPP2 | c.760G>C p.E254Q | Missense Mutation (SNP) | VAF 9/178 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV50047158, COSV50049424; called by muse, mutect2
- URB1 | c.1903C>T p.R635* | Nonsense Mutation (SNP) | VAF 12/210 reads (6%) | catalogued as rs1171138023; called by muse, mutect2
- USH2A | c.9135C>A p.N3045K | Missense Mutation (SNP) | VAF 30/340 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.401); catalogued as rs1181564648, COSV100240443; called by muse, mutect2
- UTP20 | c.4711G>C p.E1571Q | Missense Mutation (SNP) | VAF 9/182 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV55381458; called by muse, mutect2
- XKR3 | c.1234C>A p.R412S | Missense Mutation (SNP) | VAF 28/239 reads (12%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.005); catalogued as COSV58886357; called by muse, mutect2, varscan2
- YIPF7 | c.100G>T p.D34Y | Missense Mutation (SNP) | VAF 55/579 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1468514426; called by muse, mutect2
- ZFHX3 | c.529G>C p.A177P | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs772845316, COSV51712345; called by muse, mutect2, varscan2
- ZNF292 | c.3338A>T p.Q1113L | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV60549805; called by muse, mutect2
- ZNF479 | c.499G>T p.G167C | Missense Mutation (SNP) | VAF 19/232 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV100482998, COSV58638391; called by muse, mutect2, varscan2
- A2ML1 | c.1378G>T p.G460C | Missense Mutation (SNP) | VAF 44/407 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ABCA13 | c.10511C>A p.P3504H | Missense Mutation (SNP) | VAF 40/540 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ABLIM3 | c.1392C>A p.D464E | Missense Mutation (SNP) | VAF 35/371 reads (9%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.559); called by muse, mutect2
- ADAMTS12 | c.2575G>C p.V859L | Missense Mutation (SNP) | VAF 74/300 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- ADGRB2 | c.4161G>C p.K1387N | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AKR1B15 | c.466A>G p.K156E | Missense Mutation (SNP) | VAF 27/291 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2
- ALDH7A1 | c.507G>T p.L169F | Missense Mutation (SNP) | VAF 35/429 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.015); called by muse, mutect2
- ALMS1 | c.6103G>A p.D2035N | Missense Mutation (SNP) | VAF 23/412 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.987); called by muse, mutect2
- AMPH | c.743C>A p.A248E | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2
- ANGPT1 | c.626T>A p.L209* | Nonsense Mutation (SNP) | VAF 57/296 reads (19%) | called by muse, mutect2, varscan2
- ANKRD13C | c.889G>T p.E297* | Nonsense Mutation (SNP) | VAF 24/187 reads (13%) | called by muse, varscan2
- APPL2 | c.154-1G>A p.X52_splice | Splice Site (SNP) | VAF 15/349 reads (4%) | called by muse, mutect2
- ARFGEF1 | c.4463G>T p.C1488F | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.688); called by muse, mutect2
- ARHGAP11A | c.2793G>T p.M931I | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.015); called by muse, mutect2
- ARMCX5 | c.583C>T p.Q195* | Nonsense Mutation (SNP) | VAF 8/70 reads (11%) | called by muse, mutect2, varscan2
- ARRDC5 | c.917C>T p.T306I (on ENST00000381781; = p.T292I on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/229 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- ATP8A1 | c.3130A>T p.M1044L | Missense Mutation (SNP) | VAF 31/296 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- BCO2 | c.1190A>T p.D397V | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- BMS1 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 18/462 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2
- BRD2 | c.1789A>G p.S597G | Missense Mutation (SNP) | VAF 24/291 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2
- C19orf38 | c.614C>T p.S205F | Missense Mutation (SNP) | VAF 11/246 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.054); called by muse, mutect2
- C1orf167 | c.1600G>T p.A534S | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT deleterious (0.01); called by muse, mutect2
- C2orf69 | c.439A>G p.I147V | Missense Mutation (SNP) | VAF 18/340 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.306); called by muse, mutect2
- CAMSAP1 | c.2775G>T p.E925D | Missense Mutation (SNP) | VAF 25/229 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCDC113 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.009); called by muse, mutect2
- CDON | c.1904G>A p.G635E | Missense Mutation (SNP) | VAF 38/684 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- CEP95 | c.2182G>A p.E728K | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2
- CHIT1 | c.520G>T p.G174W | Missense Mutation (SNP) | VAF 40/695 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CHST2 | c.1331G>T p.G444V | Missense Mutation (SNP) | VAF 45/265 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- CLCN7 | c.574G>T p.V192L | Missense Mutation (SNP) | VAF 36/650 reads (6%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2
- CLCNKA | c.1812G>T p.Q604H | Missense Mutation (SNP) | VAF 34/233 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CLTC | c.4222A>G p.I1408V | Missense Mutation (SNP) | VAF 11/239 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.02); called by muse, mutect2
- CMTR2 | c.1882del p.D628Tfs*16 | Frame Shift Del (DEL) | VAF 12/81 reads (15%) | called by mutect2, pindel, varscan2
- COA7 | c.23A>T p.Q8L | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- COL11A1 | c.1909G>T p.G637* | Nonsense Mutation (SNP) | VAF 16/371 reads (4%) | called by muse, mutect2
- COL7A1 | c.266+1G>T p.X89_splice | Splice Site (SNP) | VAF 12/256 reads (5%) | called by muse, mutect2
- CPS1 | c.3907G>T p.A1303S | Missense Mutation (SNP) | VAF 22/290 reads (8%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2
- CRYBG2 | c.3070G>T p.G1024C | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); called by mutect2, varscan2
- CTNNA2 | c.535T>A p.F179I | Missense Mutation (SNP) | VAF 12/287 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.403); called by muse, mutect2
- CYP2A7 | c.1044G>C p.K348N | Missense Mutation (SNP) | VAF 16/163 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.924); called by muse, mutect2
- CYP3A7 | c.267G>T p.M89I | Missense Mutation (SNP) | VAF 16/322 reads (5%) | SIFT tolerated (0.81); PolyPhen benign (0.011); called by muse, mutect2
- CYP4A11 | c.305C>G p.P102R | Missense Mutation (SNP) | VAF 31/303 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DAPK2 | c.412A>T p.N138Y | Missense Mutation (SNP) | VAF 19/361 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.027); called by muse, mutect2
- DDX17 | c.95C>A p.A32E | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- DDX4 | c.536G>T p.G179V | Missense Mutation (SNP) | VAF 12/228 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.856); called by muse, mutect2
- DGKI | c.2524G>C p.V842L | Missense Mutation (SNP) | VAF 32/284 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- DIAPH3 | c.1116G>T p.E372D (on ENST00000400324 / NM_001042517.2; = p.E109D on NM_030932.3) | Missense Mutation (SNP) | VAF 22/253 reads (9%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.987); called by muse, mutect2
- DLG5 | c.3148G>T p.A1050S | Missense Mutation (SNP) | VAF 15/327 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.013); called by muse, mutect2
- DMC1 | c.694G>C p.D232H | Missense Mutation (SNP) | VAF 22/442 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EEPD1 | c.707G>T p.G236V | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.984); called by muse, mutect2
- ELAPOR2 | c.1621G>T p.V541L (on ENST00000450689 / NM_001142749.3; = p.V374L on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.918); called by muse, mutect2
- EPHA6 | c.3334A>T p.S1112C | Missense Mutation (SNP) | VAF 18/376 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ERMAP | c.223C>G p.Q75E | Missense Mutation (SNP) | VAF 24/225 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- FAM171A1 | c.2185A>G p.R729G | Missense Mutation (SNP) | VAF 21/504 reads (4%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.998); called by muse, mutect2
- FAM25A | c.218T>A p.V73D | Missense Mutation (SNP) | VAF 40/624 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.904); called by muse, mutect2
- FH | c.1091G>T p.G364V | Missense Mutation (SNP) | VAF 51/480 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- FLRT2 | c.429C>A p.N143K | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- FLRT2 | c.486dup p.L163Ifs*6 | Frame Shift Ins (INS) | VAF 6/52 reads (12%) | called by pindel, varscan2
- GAB4 | c.1628A>T p.Q543L | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.017); called by muse, mutect2
- GH2 | c.362G>T p.S121I | Missense Mutation (SNP) | VAF 10/169 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); called by muse, mutect2
- GOLGA3 | c.1066G>T p.G356C | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPR158 | c.3050G>T p.G1017V | Missense Mutation (SNP) | VAF 28/597 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.034); called by muse, mutect2
- GRIN2A | c.1291A>G p.R431G | Missense Mutation (SNP) | VAF 38/882 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.101); called by muse, mutect2
- GUCY1B1 | c.6C>A p.Y2* | Nonsense Mutation (SNP) | VAF 25/166 reads (15%) | called by muse, mutect2, varscan2
- GUCY2F | c.3231C>A p.D1077E | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HHIPL1 | c.333C>G p.C111W | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IFT172 | c.360G>T p.W120C | Missense Mutation (SNP) | VAF 28/320 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- IFT74 | c.348G>C p.Q116H | Missense Mutation (SNP) | VAF 5/112 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.015); called by muse, mutect2
- IGHV3OR16-8 | c.198G>T p.W66C | Missense Mutation (SNP) | VAF 80/812 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGSF9B | c.759G>T p.E253D | Missense Mutation (SNP) | VAF 20/419 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.014); called by muse, mutect2
- INSRR | c.3305G>C p.G1102A | Missense Mutation (SNP) | VAF 34/650 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- INSRR | c.1562A>G p.Y521C | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ITM2A | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 15/198 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.477); called by muse, mutect2
- ITSN1 | c.2013G>C p.Q671H | Missense Mutation (SNP) | VAF 16/326 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2
- JAM3 | c.499C>A p.P167T | Missense Mutation (SNP) | VAF 42/646 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KAT6A | c.4599G>T p.M1533I | Missense Mutation (SNP) | VAF 37/359 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- KDR | c.1395G>T p.E465D | Missense Mutation (SNP) | VAF 18/272 reads (7%) | SIFT tolerated (0.63); PolyPhen benign (0.005); called by muse, mutect2
- KIAA1549 | c.3994C>T p.Q1332* | Nonsense Mutation (SNP) | VAF 12/181 reads (7%) | called by muse, mutect2
- KIF17 | c.1933G>C p.V645L | Missense Mutation (SNP) | VAF 15/240 reads (6%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); called by muse, mutect2
- KIF22 | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 9/163 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.425); called by muse, mutect2
- KIF26A | c.1156C>G p.R386G | Missense Mutation (SNP) | VAF 29/292 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- KNG1 | c.1043G>T p.S348I | Missense Mutation (SNP) | VAF 36/774 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.015); called by muse, mutect2
- KPRP | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- KRT222 | c.381C>G p.N127K | Missense Mutation (SNP) | VAF 45/480 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2
- KRTAP20-4 | c.110G>T p.C37F | Missense Mutation (SNP) | VAF 44/354 reads (12%) | PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- LAMA2 | c.3419T>C p.V1140A | Missense Mutation (SNP) | VAF 28/555 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2
- LARS1 | c.1877G>T p.R626I (on ENST00000394434 / NM_020117.11; = p.R599I on NM_016460.3) | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2
- LATS1 | c.2370G>A p.M790I | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- LATS2 | c.1244G>T p.R415L | Missense Mutation (SNP) | VAF 21/201 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- LDB3 | c.840G>T p.Q280H | Missense Mutation (SNP) | VAF 11/210 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.023); called by muse, mutect2
- LIG4 | c.2693T>C p.I898T | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2
- LILRB2 | c.1567C>A p.P523T | Missense Mutation (SNP) | VAF 14/219 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2
- LRFN2 | c.1889G>T p.G630V | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.076); called by muse, mutect2
- LY75 | c.712C>G p.L238V | Missense Mutation (SNP) | VAF 10/308 reads (3%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2
- LYPD1 | c.314T>C p.L105P | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MAN1C1 | c.1520G>C p.R507T | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT tolerated (0.7); PolyPhen benign (0.026); called by muse, mutect2
- MAP2 | c.2972G>A p.G991E | Missense Mutation (SNP) | VAF 13/377 reads (3%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.028); called by muse, mutect2
- MDGA2 | c.2295G>C p.K765N (on ENST00000399232 / NM_001113498.2; = p.K467N on NM_182830.4) | Missense Mutation (SNP) | VAF 30/371 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); called by muse, mutect2
- MOV10L1 | c.1930C>G p.H644D | Missense Mutation (SNP) | VAF 32/410 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.907); called by muse, mutect2
- MYF5 | c.557A>T p.Y186F | Missense Mutation (SNP) | VAF 31/395 reads (8%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.85); called by muse, mutect2
- MYH7 | c.13G>C p.E5Q | Missense Mutation (SNP) | VAF 24/326 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2
- MYO18A | c.5079G>C p.E1693D | Missense Mutation (SNP) | VAF 20/262 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- NALCN | c.1432C>A p.Q478K | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); called by muse, varscan2
- NFIB | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 8/151 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.178); called by muse, mutect2
- NPAS3 | c.1614G>C p.E538D (on ENST00000356141 / NM_001164749.2; = p.E506D on NM_022123.3) | Missense Mutation (SNP) | VAF 32/512 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, mutect2
- OR10R2 | c.132G>T p.Q44H | Missense Mutation (SNP) | VAF 25/352 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- OR5D18 | c.289G>T p.G97* | Nonsense Mutation (SNP) | VAF 16/392 reads (4%) | called by muse, mutect2
- OR5M1 | c.265C>A p.Q89K | Missense Mutation (SNP) | VAF 16/364 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- OR6K6 | c.765G>A p.M255I (on ENST00000368144; = p.M231I on NM_001005184.1) | Missense Mutation (SNP) | VAF 22/238 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- OR7G1 | c.235C>A p.P79T | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.45); called by muse, mutect2
- OTOGL | c.1406G>T p.G469V (on ENST00000547103; = p.G460V on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/271 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, mutect2
- PANK2 | c.805G>T p.E269* | Nonsense Mutation (SNP) | VAF 28/342 reads (8%) | called by muse, mutect2
- PBLD | c.134C>G p.S45C | Missense Mutation (SNP) | VAF 22/520 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCDHB5 | c.2275G>A p.G759R | Missense Mutation (SNP) | VAF 30/241 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PDGFRA | c.1397C>A p.A466D | Missense Mutation (SNP) | VAF 44/550 reads (8%) | SIFT tolerated (0.6); PolyPhen benign (0.265); called by muse, mutect2
- PKN3 | c.890G>C p.G297A | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- POLR3A | c.2446A>T p.R816W | Missense Mutation (SNP) | VAF 54/499 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPARG | c.1502A>G p.Y501C (on ENST00000287820 / NM_015869.5; = p.Y471C on NM_005037.7) | Missense Mutation (SNP) | VAF 24/507 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2
- PPP1R16B | c.1188G>T p.K396N | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2
- PPP4R3C | c.101A>T p.Q34L | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- PRAMEF8 | c.1009G>T p.E337* | Nonsense Mutation (SNP) | VAF 40/1522 reads (3%) | called by muse, mutect2
- PRDM2 | c.908A>G p.N303S | Missense Mutation (SNP) | VAF 13/400 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- PRKAR2B | c.704C>T p.T235I | Missense Mutation (SNP) | VAF 17/301 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PRR27 | c.270_271del p.I90Mfs*17 | Frame Shift Del (DEL) | VAF 41/411 reads (10%) | called by mutect2, pindel*
- PTK2 | c.892C>T p.Q298* | Nonsense Mutation (SNP) | VAF 89/513 reads (17%) | called by muse, mutect2, varscan2
- PTPRZ1 | c.3685T>A p.S1229T | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- RAB1B | c.300G>T p.K100N | Missense Mutation (SNP) | VAF 8/133 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.028); called by muse, mutect2
- RAB44 | c.460A>G p.M154V | Missense Mutation (SNP) | VAF 27/202 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RBM28 | c.793G>T p.V265L | Missense Mutation (SNP) | VAF 44/470 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.013); called by muse, mutect2
- RBSN | c.836A>G p.Y279C | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SAGE1 | c.115G>T p.V39F | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- SAMM50 | c.936+1G>T p.X312_splice | Splice Site (SNP) | VAF 13/227 reads (6%) | called by muse, mutect2
- SCN8A | c.229G>C p.V77L | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2
- SELPLG | c.976A>T p.I326F | Missense Mutation (SNP) | VAF 25/254 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- SEMA5A | c.2293A>T p.T765S | Missense Mutation (SNP) | VAF 12/191 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.852); called by muse, mutect2
- SHCBP1L | c.1891C>G p.L631V | Missense Mutation (SNP) | VAF 16/312 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- SIX1 | c.298_314del p.G100Rfs*48 | Frame Shift Del (DEL) | VAF 32/252 reads (13%) | called by mutect2, pindel
- SKOR2 | c.2569C>T p.P857S | Missense Mutation (SNP) | VAF 31/311 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.022); called by muse, mutect2
- SLC26A5 | c.1103A>T p.Q368L | Missense Mutation (SNP) | VAF 18/241 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.166); called by muse, mutect2
- SLC2A4 | c.617T>A p.L206Q | Missense Mutation (SNP) | VAF 63/517 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- SLIT2 | c.3622G>T p.V1208L | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.015); called by muse, mutect2
- SNRNP200 | c.1271C>T p.A424V | Missense Mutation (SNP) | VAF 18/516 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.017); called by muse, mutect2
- SNTG2 | c.1608G>T p.M536I | Missense Mutation (SNP) | VAF 32/302 reads (11%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- SORCS1 | c.2029G>T p.D677Y | Missense Mutation (SNP) | VAF 17/249 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SPP1 | c.472G>T p.G158C (on ENST00000395080 / NM_001040058.2; = p.G144C on NM_000582.2) | Missense Mutation (SNP) | VAF 69/333 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SRCAP | c.3125C>T p.P1042L | Missense Mutation (SNP) | VAF 29/178 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); called by muse, mutect2
- SRXN1 | c.58G>T p.E20* | Nonsense Mutation (SNP) | VAF 5/77 reads (6%) | called by muse, mutect2
- STK32B | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 10/213 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- STX3 | c.742G>C p.D248H | Missense Mutation (SNP) | VAF 8/219 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); called by muse, mutect2
- SUCNR1 | c.232A>C p.M78L | Missense Mutation (SNP) | VAF 37/197 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SYNE1 | c.18583C>G p.Q6195E (on ENST00000367255 / NM_182961.4; = p.Q6124E on NM_033071.3) | Missense Mutation (SNP) | VAF 109/959 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TAF1L | c.5212G>A p.E1738K | Missense Mutation (SNP) | VAF 22/312 reads (7%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.187); called by muse, mutect2
- TANGO6 | c.2462A>T p.N821I | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TEK | c.1977G>C p.W659C | Missense Mutation (SNP) | VAF 22/286 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TEX36 | c.285G>T p.W95C | Missense Mutation (SNP) | VAF 18/400 reads (5%) | SIFT deleterious, low confidence (0.03); called by muse, mutect2
- TG | c.1573G>T p.G525* | Nonsense Mutation (SNP) | VAF 104/760 reads (14%) | called by muse, mutect2, varscan2
- TLE4 | c.1862G>T p.G621V | Missense Mutation (SNP) | VAF 51/567 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- TMEM244 | c.387G>T p.*129Yext*3 | Nonstop Mutation (SNP) | VAF 20/340 reads (6%) | called by muse, mutect2
- TRAV10 | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2
- TRHDE | c.1907G>T p.S636I | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.034); called by muse, mutect2
- TRHDE | c.1907+1G>T p.X636_splice | Splice Site (SNP) | VAF 12/171 reads (7%) | called by muse, mutect2
- TRIM39 | c.1169C>G p.S390* | Nonsense Mutation (SNP) | VAF 15/294 reads (5%) | called by muse, mutect2
- TRIM64B | c.158C>A p.P53H | Missense Mutation (SNP) | VAF 40/1438 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- TRIM64B | c.157C>A p.P53T | Missense Mutation (SNP) | VAF 41/1425 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- UGT1A9 | c.61G>A p.G21S | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.967); called by muse, mutect2
- ULK3 | c.45C>G p.I15M | Missense Mutation (SNP) | VAF 8/200 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.409); called by muse, mutect2
- UNC45B | c.1460G>A p.C487Y | Missense Mutation (SNP) | VAF 12/236 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- UTRN | c.7028A>T p.D2343V | Missense Mutation (SNP) | VAF 37/498 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.315); called by muse, mutect2
- UTRN | c.7030C>T p.H2344Y | Missense Mutation (SNP) | VAF 38/496 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.012); called by muse, mutect2
- VPS35 | c.1698G>T p.Q566H | Missense Mutation (SNP) | VAF 12/294 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.092); called by muse, mutect2
- WDR91 | c.986G>T p.R329L | Missense Mutation (SNP) | VAF 24/440 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZDBF2 | c.5960T>C p.I1987T | Missense Mutation (SNP) | VAF 10/183 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.011); called by muse, mutect2
- ZFP42 | c.302G>A p.G101E | Missense Mutation (SNP) | VAF 50/356 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZFP92 | c.1186G>A p.V396M | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- ZFPM2 | c.2443G>C p.D815H | Missense Mutation (SNP) | VAF 40/789 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.365); called by muse, mutect2
- ZNF446 | c.1212C>A p.F404L | Missense Mutation (SNP) | VAF 20/304 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); called by muse, mutect2
- ZNF853 | c.1462G>T p.G488W | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- ZNF99 | c.1574G>A p.R525K | Missense Mutation (SNP) | VAF 47/504 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ABCA13 | c.60C>A p.L20= | Silent (SNP) | VAF 46/361 reads (13%) | catalogued as rs1427775953; called by muse, mutect2, varscan2
- AC018709.1 | c.252C>T p.L84= | Silent (SNP) | VAF 14/337 reads (4%) | called by muse, mutect2
- AC098582.1 | c.2595A>T p.I865= | Silent (SNP) | VAF 7/139 reads (5%) | catalogued as rs1213317334; called by muse, mutect2
- ACOT11 | c.1758G>A p.L586= | Silent (SNP) | VAF 7/89 reads (8%) | called by muse, mutect2
- ADGRV1 | c.6171A>G p.T2057= | Silent (SNP) | VAF 18/354 reads (5%) | called by muse, mutect2
- ANKDD1B | c.987C>T p.I329= | Silent (SNP) | VAF 8/135 reads (6%) | catalogued as COSV101552549; called by muse, mutect2
- ANKRD7 | c.474G>C p.G158= | Silent (SNP) | VAF 20/184 reads (11%) | called by muse, mutect2
- ATP2B4 | c.804G>T p.R268= | Silent (SNP) | VAF 28/344 reads (8%) | called by muse, mutect2
- BARX1 | c.183G>T p.V61= | Silent (SNP) | VAF 24/158 reads (15%) | called by muse, mutect2, varscan2
- BPIFB6 | c.273G>T p.V91= | Silent (SNP) | VAF 27/348 reads (8%) | catalogued as COSV100848519; called by muse, mutect2
- BRD7 | c.966G>T p.V322= | Silent (SNP) | VAF 10/254 reads (4%) | called by muse, mutect2
- C8orf34 | c.807G>T p.V269= | Silent (SNP) | VAF 29/139 reads (21%) | called by muse, mutect2, varscan2
- CHRNB3 | c.999C>T p.P333= | Silent (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- CIT | c.3228G>A p.A1076= | Silent (SNP) | VAF 7/142 reads (5%) | catalogued as rs1393440175; called by muse, mutect2
- CUX2 | c.4353G>A p.V1451= | Silent (SNP) | VAF 19/353 reads (5%) | called by muse, mutect2
- CXCR2 | c.825C>A p.T275= | Silent (SNP) | VAF 14/175 reads (8%) | called by muse, mutect2
- DAPK2 | c.411G>T p.V137= | Silent (SNP) | VAF 20/366 reads (5%) | called by muse, mutect2
- DGAT1 | c.1284C>T p.L428= | Silent (SNP) | VAF 10/302 reads (3%) | called by muse, mutect2
- DIO2 | c.426C>A p.A142= | Silent (SNP) | VAF 11/155 reads (7%) | catalogued as COSV70445196, COSV70445273; called by muse, mutect2
- DNAH11 | c.9300G>T p.V3100= | Silent (SNP) | VAF 14/91 reads (15%) | called by muse, mutect2
- DNAH12 | c.1353C>A p.L451= | Silent (SNP) | VAF 10/203 reads (5%) | called by muse, mutect2
- EIF2AK1 | c.915G>A p.V305= | Silent (SNP) | VAF 24/544 reads (4%) | called by muse, mutect2
- EVC | c.2436G>A p.L812= | Silent (SNP) | VAF 40/764 reads (5%) | called by muse, mutect2
- FAM205A | c.567G>A p.T189= | Silent (SNP) | VAF 30/326 reads (9%) | catalogued as rs1271179813, COSV101113042; called by muse, mutect2
- GDNF | c.345C>T p.N115= | Silent (SNP) | VAF 22/418 reads (5%) | catalogued as rs112722327; called by muse, mutect2
- GOLGA6L7 | c.132C>A p.G44= | Silent (SNP) | VAF 18/280 reads (6%) | catalogued as COSV73845741; called by muse, mutect2
- GPR37 | c.1446G>T p.R482= | Silent (SNP) | VAF 20/322 reads (6%) | called by muse, mutect2
- HLA-DRA | c.477G>A p.E159= | Silent (SNP) | VAF 27/546 reads (5%) | called by muse, mutect2
- HTR3A | c.789C>A p.G263= | Silent (SNP) | VAF 18/266 reads (7%) | called by muse, mutect2
- HYDIN | c.1404G>T p.L468= | Silent (SNP) | VAF 8/98 reads (8%) | called by muse, mutect2
- INSC | c.450G>T p.V150= | Silent (SNP) | VAF 13/145 reads (9%) | called by muse, mutect2
- IPO9 | c.1539G>A p.L513= | Silent (SNP) | VAF 20/163 reads (12%) | called by muse, mutect2, varscan2
- KCNH8 | c.3165C>T p.F1055= | Silent (SNP) | VAF 24/379 reads (6%) | catalogued as rs1559375667; called by muse, mutect2
- KDR | c.3699T>G p.P1233= | Silent (SNP) | VAF 42/358 reads (12%) | catalogued as rs772902095; called by muse, mutect2, varscan2
- LINGO2 | c.546C>A p.L182= | Silent (SNP) | VAF 20/234 reads (9%) | called by muse, mutect2
- MBD6 | c.2334C>T p.L778= | Silent (SNP) | VAF 10/126 reads (8%) | called by muse, mutect2
- MEOX2 | c.807A>G p.P269= | Silent (SNP) | VAF 50/570 reads (9%) | called by muse, mutect2
- MGAT4C | c.906C>A p.I302= | Silent (SNP) | VAF 68/381 reads (18%) | called by muse, mutect2, varscan2
- NR1H4 | c.1257G>A p.E419= (on ENST00000551379 / NM_001206993.2; = p.E405= on NM_005123.4) | Silent (SNP) | VAF 42/292 reads (14%) | catalogued as rs1266910992; called by muse, mutect2, varscan2
- NRXN2 | c.2961G>A p.L987= | Silent (SNP) | VAF 18/310 reads (6%) | catalogued as COSV99634198; called by muse, mutect2
- OR4N5 | c.633C>T p.F211= | Silent (SNP) | VAF 18/240 reads (8%) | catalogued as COSV61321028; called by muse, mutect2
- PCDHGB3 | c.1146C>A p.I382= | Silent (SNP) | VAF 42/476 reads (9%) | catalogued as COSV54019206; called by muse, mutect2
- PLEC | c.11229T>A p.A3743= (on ENST00000322810 / NM_201380.4; = p.A3633= on NM_000445.5) | Silent (SNP) | VAF 164/831 reads (20%) | called by muse, mutect2, varscan2
- PLEC | c.4569G>T p.A1523= (on ENST00000322810 / NM_201380.4; = p.A1413= on NM_000445.5) | Silent (SNP) | VAF 42/215 reads (20%) | catalogued as COSV100516066; called by muse, mutect2, varscan2
- PODNL1 | c.270C>T p.L90= | Silent (SNP) | VAF 16/204 reads (8%) | called by muse, mutect2
- PSMC3IP | c.6T>C p.S2= | Silent (SNP) | VAF 61/505 reads (12%) | called by muse, mutect2, varscan2
- RBM47 | c.588C>T p.F196= | Silent (SNP) | VAF 8/116 reads (7%) | catalogued as rs1392253835, COSV99920212; called by muse, mutect2
- RPL27 | c.159G>T p.V53= | Silent (SNP) | VAF 22/444 reads (5%) | catalogued as COSV53815450; called by muse, mutect2
- RRNAD1 | c.444G>A p.L148= | Silent (SNP) | VAF 16/281 reads (6%) | called by muse, mutect2
- SHANK2 | c.2490G>T p.G830= | Silent (SNP) | VAF 18/528 reads (3%) | called by muse, mutect2
- SI | c.1707C>T p.A569= | Silent (SNP) | VAF 47/520 reads (9%) | catalogued as COSV104387799; called by muse, mutect2
- SLC34A1 | c.411C>T p.F137= | Silent (SNP) | VAF 26/670 reads (4%) | called by muse, mutect2
- SLC4A1 | c.2298C>A p.V766= | Silent (SNP) | VAF 36/355 reads (10%) | catalogued as COSV99293783; called by muse, mutect2, varscan2
- SLC7A11 | c.891G>C p.L297= | Silent (SNP) | VAF 91/534 reads (17%) | called by muse, mutect2, varscan2
- SPATA32 | c.210G>T p.P70= | Silent (SNP) | VAF 28/530 reads (5%) | called by muse, mutect2
- SPOCK3 | c.979C>A p.R327= | Silent (SNP) | VAF 58/399 reads (15%) | catalogued as COSV62723966; called by muse, mutect2, varscan2
- SRCAP | c.3123C>T p.V1041= | Silent (SNP) | VAF 29/178 reads (16%) | called by muse, mutect2
- TCP11L2 | c.1428A>T p.L476= | Silent (SNP) | VAF 16/314 reads (5%) | called by muse, mutect2
- TEP1 | c.7870C>T p.L2624= | Silent (SNP) | VAF 24/298 reads (8%) | catalogued as COSV52997810; called by muse, mutect2
- TEP1 | c.3570G>T p.G1190= | Silent (SNP) | VAF 15/108 reads (14%) | called by muse, mutect2, varscan2
- TERT | c.540T>A p.A180= | Silent (SNP) | VAF 124/485 reads (26%) | called by muse, mutect2, varscan2
- TKTL2 | c.585C>T p.P195= | Silent (SNP) | VAF 49/296 reads (17%) | catalogued as rs773453054; called by muse, mutect2, varscan2
- TNXB | c.9825C>T p.R3275= (on ENST00000647633; = p.R3028= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/140 reads (6%) | catalogued as rs1378651176, COSV64487926; called by muse, mutect2
- TP63 | c.879C>A p.P293= | Silent (SNP) | VAF 15/416 reads (4%) | catalogued as COSV99287691; called by muse, mutect2
- TRAPPC9 | c.3408G>T p.L1136= | Silent (SNP) | VAF 14/368 reads (4%) | called by muse, mutect2
- TRIM10 | c.570A>C p.A190= | Silent (SNP) | VAF 42/312 reads (13%) | called by muse, mutect2, varscan2
- TRIM39 | c.1422C>T p.V474= | Silent (SNP) | VAF 30/572 reads (5%) | catalogued as rs759836871; called by muse, mutect2
- TRIM42 | c.1701C>A p.P567= | Silent (SNP) | VAF 13/303 reads (4%) | called by muse, mutect2
- TRIM7 | c.727C>A p.R243= | Silent (SNP) | VAF 54/648 reads (8%) | catalogued as rs61739211; called by muse, mutect2
- TRNAU1AP | c.219C>T p.A73= | Silent (SNP) | VAF 21/191 reads (11%) | called by muse, mutect2, varscan2
- TYRP1 | c.144G>C p.V48= | Silent (SNP) | VAF 18/300 reads (6%) | called by muse, mutect2
- WIPF1 | c.1041G>T p.P347= | Silent (SNP) | VAF 9/200 reads (5%) | catalogued as COSV55818501; called by muse, mutect2
- AC016582.1 | chr19:37824471 G>A | 3'Flank (SNP) | VAF 8/168 reads (5%) | called by muse, mutect2
- AC068633.1 | n.339C>A | RNA (SNP) | VAF 16/206 reads (8%) | called by muse, mutect2
- AC245047.1 | n.116C>G | RNA (SNP) | VAF 13/150 reads (9%) | called by muse, mutect2
- ACTN2 | c.-34C>T | 5'UTR (SNP) | VAF 13/140 reads (9%) | catalogued as rs374500536; called by muse, mutect2
- AKR1B15 | c.150+770C>T | Intron (SNP) | VAF 21/324 reads (6%) | called by muse, mutect2
- AL353804.6 | chrX:73829164 C>A | 3'Flank (SNP) | VAF 22/155 reads (14%) | called by muse, mutect2
- ARHGAP27P2 | n.459G>T | RNA (SNP) | VAF 15/213 reads (7%) | called by muse, mutect2
- BCL11A | chr2:60452632 C>A | 3'Flank (SNP) | VAF 38/472 reads (8%) | called by muse, mutect2
- C16orf82 | c.-17C>A | 5'UTR (SNP) | VAF 38/314 reads (12%) | called by muse, mutect2
- C16orf82 | c.-16C>A | 5'UTR (SNP) | VAF 35/305 reads (11%) | called by muse, mutect2, varscan2
- CACNA1B | c.530+9139G>T | Intron (SNP) | VAF 10/110 reads (9%) | called by muse, mutect2
- CCL4L2 | c.-60T>C | 5'UTR (SNP) | VAF 38/794 reads (5%) | called by muse, mutect2
- CLNK | c.630+508G>T | Intron (SNP) | VAF 22/280 reads (8%) | called by muse, mutect2
- COLCA2 | chr11:111296336 C>G | 5'Flank (SNP) | VAF 16/362 reads (4%) | called by muse, mutect2
- CREB5 | chr7:28410506 C>G | 5'Flank (SNP) | VAF 18/504 reads (4%) | called by muse, mutect2
- CYP4V2 | c.988-51A>G | Intron (SNP) | VAF 37/324 reads (11%) | called by mutect2, varscan2
- DDIT3 | c.-81+1205G>A | Intron (SNP) | VAF 20/531 reads (4%) | catalogued as rs1206152456; called by muse, mutect2
- EIF2AK1 | c.118+790C>A | Intron (SNP) | VAF 16/344 reads (5%) | catalogued as rs1261785670; called by muse, mutect2
- FLJ40194 | n.280G>A | RNA (SNP) | VAF 10/284 reads (4%) | called by muse, mutect2
- FOXL2 | c.-32A>T | 5'UTR (SNP) | VAF 35/153 reads (23%) | called by muse, mutect2, varscan2
- GAP43 | c.31-12156C>T | Intron (SNP) | VAF 16/337 reads (5%) | called by muse, mutect2
- HK1 | chr10:69315932 G>C | 5'Flank (SNP) | VAF 40/626 reads (6%) | called by muse, mutect2
- HOXA6 | chr7:27151662 G>T | 5'Flank (SNP) | VAF 34/509 reads (7%) | called by muse, mutect2
- IL10RA | c.*986G>C | 3'UTR (SNP) | VAF 26/460 reads (6%) | called by muse, mutect2
- LIFR | c.*3G>T | 3'UTR (SNP) | VAF 179/472 reads (38%) | called by muse, mutect2, varscan2
- LINC00544 | n.766C>A | RNA (SNP) | VAF 39/403 reads (10%) | called by muse, mutect2
- LINC00602 | n.1048C>G | RNA (SNP) | VAF 8/84 reads (10%) | called by muse, mutect2
- MGAM | c.4619-12470C>G | Intron (SNP) | VAF 48/480 reads (10%) | called by muse, mutect2
- MIR6859-4 | chr16:17308 G>T | 5'Flank (SNP) | VAF 30/934 reads (3%) | called by muse, mutect2
- NFAM1 | c.*19T>C | 3'UTR (SNP) | VAF 14/264 reads (5%) | catalogued as rs1017526306; called by muse, mutect2
- NIPA1 | c.*18G>T | 3'UTR (SNP) | VAF 18/420 reads (4%) | called by muse, mutect2
- NKX3-2 | c.-1G>A | 5'UTR (SNP) | VAF 16/163 reads (10%) | called by muse, mutect2
- PADI2 | c.-25G>A | 5'UTR (SNP) | VAF 8/144 reads (6%) | called by muse, mutect2
- PAX6 | chr11:31789824 G>A | 3'Flank (SNP) | VAF 17/420 reads (4%) | called by muse, mutect2
- PIWIL1 | c.2469+13A>G | Intron (SNP) | VAF 15/169 reads (9%) | catalogued as rs529399939; called by muse, mutect2
- PLEKHB2 | c.-106C>A | 5'UTR (SNP) | VAF 7/156 reads (4%) | called by muse, mutect2
- PTEN | c.-3G>C | 5'UTR (SNP) | VAF 31/662 reads (5%) | called by muse, mutect2
- RUNX1T1 | c.-86+4208G>T | Intron (SNP) | VAF 16/113 reads (14%) | called by muse, mutect2, varscan2
- SCN4B | c.*1429G>T | 3'UTR (SNP) | VAF 29/570 reads (5%) | called by muse, mutect2
- SMIM11P1 | n.125C>G | RNA (SNP) | VAF 27/406 reads (7%) | called by muse, mutect2
- SPATA31C2 | n.914C>A | RNA (SNP) | VAF 18/510 reads (4%) | called by muse, mutect2
- STMP1 | chr7:135660324 C>A | 5'Flank (SNP) | VAF 59/413 reads (14%) | called by muse, mutect2, varscan2
- TGFBR3 | c.*1152C>A | 3'UTR (SNP) | VAF 36/508 reads (7%) | called by muse, mutect2
- TGFBR3 | c.*581T>G | 3'UTR (SNP) | VAF 34/424 reads (8%) | called by muse, mutect2
- TM2D1 | c.-72C>T | 5'UTR (SNP) | VAF 10/101 reads (10%) | called by muse, mutect2
- TOP1MT | c.29+18G>A | Intron (SNP) | VAF 42/548 reads (8%) | called by muse, mutect2
- VSTM2A | c.*79G>A | 3'UTR (SNP) | VAF 32/388 reads (8%) | catalogued as rs1354959945, COSV68289192; called by muse, mutect2
- ZNF467 | chr7:149778019 C>A | 5'Flank (SNP) | VAF 37/516 reads (7%) | called by muse, mutect2
- ZNF827 | c.*296G>C | 3'UTR (SNP) | VAF 75/409 reads (18%) | called by muse, mutect2, varscan2
